Somatic mutation profile of tumor specimen TCGA-FA-8693-01A (aliquot TCGA-FA-8693-01A-11D-2397-10) from TCGA case TCGA-FA-8693, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 75.2 years (27,468 days).
Specimen TCGA-FA-8693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62642106-35f9-4703-91f2-2d569aea2a7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-8693-10A (Blood Derived Normal), aliquot TCGA-FA-8693-10A-01D-2397-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcf4aaaf-03c4-4ad1-96ee-099b45ca8635

The open-access MAF lists 173 somatic variants for this specimen: 133 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 38, Frame Shift Del 6, Splice Site 5, Nonsense Mutation 5, Frame Shift Ins 3, Translation Start Site 3, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 49/161 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1057519953, COSV69041526, COSV69042045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACO1 | c.1611T>G p.N537K | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100008296; called by muse, mutect2
- ADGRV1 | c.3503A>T p.E1168V | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101316143; called by muse, mutect2, varscan2
- ALX1 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100374494; called by mutect2, varscan2
- ARHGAP29 | c.681A>C p.E227D | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as COSV99558422; called by muse, mutect2, varscan2
- ARHGAP44 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99311003; called by muse, mutect2, varscan2
- ASPM | c.8372G>T p.G2791V | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV54126497; called by muse, mutect2, varscan2
- BIRC6 | c.8668C>T p.R2890* | Nonsense Mutation (SNP) | VAF 54/244 reads (22%) | catalogued as rs777227964, COSV101428424; called by muse, varscan2
- BTG2 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV51856911, COSV99305605, COSV99305919; called by muse, mutect2, varscan2
- CALCR | c.1468G>T p.A490S (on ENST00000649521 / NM_001164737.2; = p.A474S on NM_001742.4) | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs1196989174, COSV100810633; called by muse, mutect2, varscan2
- CD274 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV101056060; called by muse, mutect2, varscan2
- CD274 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056062; called by muse, mutect2, varscan2
- CD300LB | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as rs771531701, COSV58725583; called by muse, mutect2, varscan2
- CD8A | c.700T>A p.Y234N | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99374480; called by muse, mutect2, varscan2
- CDH20 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.609); catalogued as COSV99405765; called by muse, mutect2, varscan2
- CEPT1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100718714; called by muse, mutect2, varscan2
- CHRM3 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55098720, COSV99698736; called by muse, mutect2, varscan2
- CHST9 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV52434844, COSV99410344; called by muse, mutect2, varscan2
- CHTF18 | c.2885C>G p.S962C | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50210854, COSV99243195; called by muse, mutect2
- CNTNAP5 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101443739; called by muse, mutect2, varscan2
- COL21A1 | c.2715A>C p.K905N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.951); catalogued as COSV55178118, COSV99779177; called by muse, mutect2, varscan2
- COL4A3 | c.4466C>A p.T1489N | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV101170383; called by muse, mutect2, varscan2
- CPXCR1 | c.194A>G p.Q65R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV99342268; called by muse, mutect2, varscan2
- DMBT1 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 144/705 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs770763185, COSV100353369; called by muse, mutect2, varscan2
- DOCK1 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1289100385, COSV99730714; called by muse, mutect2
- DOCK5 | c.2387T>C p.L796P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.162); catalogued as COSV99377194; called by muse, mutect2, varscan2
- DPY19L2 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100116828; called by muse, mutect2, varscan2
- ENPEP | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV99487759; called by muse, mutect2, varscan2
- FCMR | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as rs1261339339, COSV100892904; called by mutect2, varscan2
- FCN2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV99391326; called by muse, mutect2, varscan2
- FGGY | c.1574+1G>T p.X525_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100365161; called by muse, mutect2, varscan2
- GABRG3 | c.837A>C p.K279N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100408240, COSV61515824; called by muse, mutect2, varscan2
- GLI2 | c.3954G>C p.E1318D (on ENST00000361492 / NM_001374353.1; = p.E1335D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV100083573; called by muse, mutect2, varscan2
- GLYR1 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100424360; called by muse, mutect2, varscan2
- GNL2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769914689, COSV56169955; called by muse, mutect2, varscan2
- GOLGA4 | c.5551A>T p.I1851F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as COSV100729001; called by muse, mutect2, varscan2
- GRIA2 | c.1150del p.R384Gfs*45 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as COSV52386086, COSV52389589; called by mutect2, pindel, varscan2
- H1-4 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs952833782, COSV99175287; called by muse, mutect2, varscan2
- H2BC13 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.991); catalogued as COSV100704403; called by muse, mutect2, varscan2
- HDDC2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1258543079, COSV100600262; called by muse, mutect2, varscan2
- HIPK1 | c.1184C>G p.A395G | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100479320; called by muse, mutect2, varscan2
- HSD3B7 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.529); catalogued as rs371576756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV4-31 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs1347220592, rs539394316; called by muse, mutect2
- INSC | c.1705T>G p.L569V | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1373223976, COSV101089348; called by muse, mutect2
- IVL | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV100908190; called by muse, mutect2, varscan2
- KCNH3 | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV99235411; called by muse, mutect2, varscan2
- KIRREL3 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1437300343, COSV69386350; called by muse, mutect2, varscan2
- KIRREL3 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as COSV69385769, COSV69386698; called by muse, mutect2, varscan2
- LRP1B | c.7138T>C p.S2380P | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV67196511, COSV67267811; called by muse, mutect2, varscan2
- LYN | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101319614; called by muse, mutect2, varscan2
- MAGI2 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62642519; called by muse, mutect2, varscan2
- MAP2K3 | c.551T>C p.L184P (on ENST00000342679 / NM_145109.3; = p.L155P on NM_002756.4) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100384093; called by muse, mutect2, varscan2
- ME1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868866711, COSV63839544; called by muse, mutect2, varscan2
- MPZL1 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as rs750771385, COSV100850364; called by muse, mutect2, varscan2
- MTNR1A | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV100208240; called by muse, mutect2, varscan2
- MYH1 | c.2099A>C p.N700T | Missense Mutation (SNP) | VAF 81/463 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV99876288; called by muse, mutect2, varscan2
- NCAM1 | c.1463A>C p.N488T (on ENST00000316851 / NM_181351.5; = p.N478T on NM_000615.7) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377991, COSV57518097; called by muse, mutect2, varscan2
- NCAPD3 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV101596372; called by muse, mutect2, varscan2
- NLGN1 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64331439, COSV64331546, COSV64347082; called by muse, mutect2, varscan2
- NOX4 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV99631083; called by muse, mutect2, varscan2
- NSD2 | c.2878A>C p.N960H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV100373566; called by muse, mutect2, varscan2
- NT5E | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 6/161 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100004212; called by muse, mutect2
- NYNRIN | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs748667976, COSV101230554; called by muse, mutect2, varscan2
- OR51I2 | c.824T>G p.L275R | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100413417; called by muse, mutect2, varscan2
- PAX1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101270330; called by muse, mutect2, varscan2
- PCDH15 | c.4709T>C p.L1570P | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100904924; called by muse, mutect2, varscan2
- PCDH17 | c.1439A>G p.Q480R | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs1566213609, COSV100931744; called by muse, mutect2, varscan2
- PCDH7 | c.908A>C p.D303A | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100688462; called by muse, mutect2
- PDCL3 | c.369-2A>G p.X123_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as rs758431306, COSV51809959; called by muse, mutect2, varscan2
- PDGFC | c.965A>G p.K322R | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV99925636; called by muse, mutect2, varscan2
- PDLIM1 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV100267816; called by muse, mutect2
- PELI1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs780701539, COSV100735147; called by muse, mutect2, varscan2
- PENK | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV59243102; called by muse, mutect2, varscan2
- PIWIL1 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV99806607; called by muse, mutect2, varscan2
- PLCD3 | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.075); catalogued as COSV100504291; called by muse, mutect2
- POU2AF1 | c.7T>C p.W3R | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101260647; called by muse, mutect2, varscan2
- PPFIA1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99557023; called by muse, mutect2, varscan2
- PROX1 | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV54783307, COSV99799700; called by muse, mutect2, varscan2
- PRPH2 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100028151; called by muse, mutect2, varscan2
- PTPRT | c.4308A>T p.E1436D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100628421; called by muse, mutect2, varscan2
- RAB8A | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99959837; called by muse, varscan2
- RABEP2 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100707103; called by muse, mutect2, varscan2
- RBMXL2 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.28); catalogued as rs1373039155, COSV100182271, COSV100182323; called by muse, mutect2, varscan2
- RFC5 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs933326302, COSV99969929; called by muse, mutect2, varscan2
- ROPN1B | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as COSV99305613; called by muse, mutect2, varscan2
- SCN1A | c.6015A>C p.K2005N (on ENST00000303395 / NM_001202435.3; = p.K1994N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV100320972; called by muse, mutect2, varscan2
- SCN9A | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV100313334; called by muse, mutect2, varscan2
- SCUBE1 | c.2852C>T p.A951V | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1205642892, COSV62609970; called by muse, mutect2, varscan2
- SDK1 | c.6247A>G p.T2083A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1203051122, COSV101269556; called by muse, mutect2, varscan2
- SEL1L3 | c.2357A>T p.Y786F | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99340579; called by muse, varscan2
- SFTPD | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs762380007, COSV100954538; called by muse, mutect2, varscan2
- SFTPD | c.317-1G>T p.X106_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV64852891; called by muse, mutect2, varscan2
- SGK1 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs141028225; called by muse, mutect2, varscan2
- SGK1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs375777416; called by muse, varscan2
- SLC18A1 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756565344, COSV99368713; called by muse, mutect2, varscan2
- SLC22A25 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV60599307; called by muse, mutect2, varscan2
- SOCS3 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58271450; called by muse, mutect2, varscan2
- SRSF1 | c.216T>G p.Y72* | Nonsense Mutation (SNP) | VAF 36/150 reads (24%) | catalogued as COSV99365419; called by muse, mutect2, varscan2
- ST7L | c.289-2A>G p.X97_splice | Splice Site (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100573823; called by muse, mutect2, varscan2
- TCF20 | c.3397C>T p.R1133W | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.993); catalogued as rs756751149, COSV100166397; called by muse, mutect2, varscan2
- TIAM1 | c.2783C>A p.P928H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99736347; called by muse, mutect2, varscan2
- TOX3 | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as rs764556506, COSV99567730; called by muse, mutect2, varscan2
- TRPC3 | c.1151T>G p.L384R (on ENST00000379645 / NM_001366479.2; = p.L311R on NM_003305.2) | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV99312934; called by muse, mutect2
- TSPAN19 | c.178T>G p.L60V | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV70813376; called by muse, mutect2, varscan2
- UBA6 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs927895712, COSV100451754; called by muse, mutect2, varscan2
- USH2A | c.8264T>G p.L2755R | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56368478; called by muse, mutect2, varscan2
- USH2A | c.6068T>C p.L2023P | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as COSV100237694; called by muse, mutect2, varscan2
- USP31 | c.844T>G p.F282V | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99565437; called by muse, mutect2, varscan2
- USP44 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99311921; called by muse, mutect2, varscan2
- VCAN | c.2533A>C p.S845R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54102912, COSV54103950; called by muse, mutect2, varscan2
- VCAN | c.4684T>G p.F1562V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99426348; called by muse, mutect2, varscan2
- VGLL3 | c.448T>G p.F150V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV101051976; called by muse, mutect2, varscan2
- WASF3 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100098913; called by muse, varscan2
- WDR72 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100854699; called by muse, mutect2, varscan2
- ZBBX | c.1501T>C p.S501P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100284362; called by muse, mutect2, varscan2
- ZBTB17 | c.536-2A>T p.X179_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100999035; called by muse, mutect2
- ZNF181 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101106320; called by muse, mutect2, varscan2
- ZNF454 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV60766837; called by muse, mutect2, varscan2
- ZNF471 | c.1455A>C p.K485N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100340700; called by muse, mutect2, varscan2
- ZNF492 | c.1114A>G p.K372E | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101514018; called by mutect2, varscan2
- ZNF835 | c.1415A>C p.K472T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101606367; called by mutect2, varscan2
- ABCB1 | c.643del p.T215Pfs*3 | Frame Shift Del (DEL) | VAF 41/191 reads (21%) | called by mutect2, pindel, varscan2
- BNC2 | c.1817dup p.P607Afs*4 | Frame Shift Ins (INS) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- EGFL6 | c.1015dup p.M339Nfs*6 | Frame Shift Ins (INS) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- GLI2 | c.260del p.P87Lfs*14 | Frame Shift Del (DEL) | VAF 42/206 reads (20%) | called by mutect2, pindel, varscan2
- IGHG1 | c.249C>G p.C83W | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPKB | c.1958del p.N653Tfs*37 | Frame Shift Del (DEL) | VAF 34/156 reads (22%) | called by mutect2, pindel, varscan2
- NF1 | c.5884dup p.H1962Pfs*2 (on ENST00000358273 / NM_001042492.3; = p.H1941Pfs*2 on NM_000267.3) | Frame Shift Ins (INS) | VAF 27/136 reads (20%) | called by mutect2, pindel, varscan2
- REST | c.872dup p.Y291* | Nonsense Mutation (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- SGK1 | c.230del p.P77Qfs*25 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- TOP2B | c.1094del p.K365Rfs*8 (on ENST00000264331 / NM_001330700.2; = p.K360Rfs*8 on NM_001068.3) | Frame Shift Del (DEL) | VAF 43/240 reads (18%) | called by mutect2, pindel, varscan2
- ABR | c.1173C>T p.I391= (on ENST00000302538 / NM_021962.5; = p.I354= on NM_001092.5) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV99348199; called by muse, mutect2, varscan2
- ATG2B | c.4698A>T p.G1566= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99952116; called by muse, mutect2, varscan2
- CELSR3 | c.2511C>G p.A837= | Silent (SNP) | VAF 78/269 reads (29%) | catalogued as COSV99373981; called by muse, mutect2, varscan2
- CPNE6 | c.837A>C p.S279= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as COSV99393537; called by muse, mutect2, varscan2
- CTTNBP2 | c.4044A>G p.Q1348= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as COSV99354251; called by muse, mutect2, varscan2
- DDX42 | c.2199T>C p.S733= | Silent (SNP) | VAF 39/193 reads (20%) | catalogued as COSV100834971; called by muse, mutect2, varscan2
- DTX2 | c.1488G>A p.S496= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as rs780357158, COSV100184687; called by muse, mutect2, varscan2
- EPB41L5 | c.255T>G p.G85= | Silent (SNP) | VAF 31/214 reads (14%) | catalogued as COSV99758880; called by muse, mutect2, varscan2
- FAT3 | c.11286C>T p.H3762= | Silent (SNP) | VAF 73/410 reads (18%) | catalogued as rs774036182, COSV53184161, COSV53188237; called by muse, mutect2, varscan2
- FRAS1 | c.8064C>T p.S2688= | Silent (SNP) | VAF 73/294 reads (25%) | catalogued as rs371145937; called by muse, mutect2, varscan2
- FREM1 | c.459G>A p.A153= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs562673690, COSV66521893; called by muse, mutect2
- FREM2 | c.1080T>C p.T360= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs778918729, COSV99749332; called by muse, mutect2, varscan2
- GNAT3 | c.180T>G p.G60= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV101242407; called by muse, mutect2, varscan2
- H4C12 | c.156C>T p.Y52= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1188912235; called by mutect2, varscan2
- IGHV4-31 | c.126T>A p.A42= | Silent (SNP) | VAF 36/600 reads (6%) | called by muse, mutect2
- INTS13 | c.1026A>C p.V342= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV99677452; called by muse, mutect2, varscan2
- IPO4 | c.2661G>A p.Q887= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100269119; called by mutect2, varscan2
- KALRN | c.1770G>A p.T590= | Silent (SNP) | VAF 46/254 reads (18%) | catalogued as rs574174504, COSV53777657, COSV53783173; called by muse, mutect2, varscan2
- MAP3K12 | c.282C>T p.C94= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV99913354; called by muse, mutect2, varscan2
- MUC16 | c.36744T>G p.R12248= | Silent (SNP) | VAF 16/362 reads (4%) | catalogued as COSV101198540, COSV101200319; called by muse, mutect2
- NECAP1 | c.423A>G p.Q141= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as COSV100331605; called by muse, mutect2
- NMBR | c.534A>G p.E178= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as COSV99237359; called by muse, mutect2, varscan2
- NRG3 | c.990A>G p.Q330= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as rs758592296, COSV100932028, COSV64545305; called by muse, mutect2, varscan2
- OR52I2 | c.354A>C p.G118= | Silent (SNP) | VAF 137/515 reads (27%) | catalogued as COSV100442921, COSV100442952; called by muse, mutect2, varscan2
- OR5AP2 | c.219T>G p.S73= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV100266280; called by muse, mutect2, varscan2
- PGM1 | c.1062G>A p.E354= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as COSV100936613; called by muse, mutect2
- PLOD2 | c.162A>C p.R54= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99282925; called by muse, mutect2, varscan2
- RNF216 | c.2550G>A p.L850= (on ENST00000425013 / NM_207116.3; = p.L907= on NM_207111.4) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV101111337; called by muse, varscan2
- SACS | c.10113T>G p.T3371= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs763834751, COSV66540935; called by muse, mutect2, varscan2
- SH2D4B | c.261T>C p.P87= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs192169537, COSV100214015; called by muse, mutect2, varscan2
- SLX4IP | c.906G>A p.A302= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs757894309, COSV100570599; called by muse, mutect2, varscan2
- SPATA31E1 | c.447C>T p.G149= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs148586576; called by muse, mutect2, varscan2
- SYT16 | c.603C>T p.S201= | Silent (SNP) | VAF 47/208 reads (23%) | catalogued as rs953514244, COSV70856123, COSV70856245; called by muse, mutect2, varscan2
- TBC1D14 | c.1359T>C p.G453= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV101298979; called by muse, mutect2, varscan2
- TMX4 | c.120G>A p.Q40= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1010758435, COSV99851541; called by muse, mutect2
- UNC45B | c.1623C>T p.D541= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs531660473, COSV99268851; called by muse, varscan2
- ZFC3H1 | c.3915T>C p.D1305= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV101110604; called by muse, mutect2, varscan2
- ZNF629 | c.573G>A p.S191= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99354884; called by muse, mutect2, varscan2
- BIRC8 | n.1558C>A | RNA (SNP) | VAF 15/98 reads (15%) | catalogued as COSV100136424, COSV58843607; called by muse, mutect2, varscan2
- KIF16B | c.3498+3141C>T | Intron (SNP) | VAF 24/174 reads (14%) | catalogued as COSV100733549; called by muse, mutect2, varscan2
